Somatic mutation profile of tumor specimen ALCH-B3CJ-TTP1-A (aliquot ALCH-B3CJ-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3CJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,123 days).
Specimen ALCH-B3CJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79cde7c3-7f95-4944-ad15-4df7a95d974b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CJ-NB1-A (Blood Derived Normal), aliquot ALCH-B3CJ-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/833c494e-1e9f-4f02-9194-be888821c095

The open-access MAF lists 474 somatic variants for this specimen: 327 protein-altering or splice-affecting, 87 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 87, Intron 30, Nonsense Mutation 26, 5'UTR 11, Splice Site 9, Frame Shift Del 7, Splice Region 6, 5'Flank 6, 3'Flank 6, RNA 4, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 76/118 reads (64%) | catalogued as rs876658593, COSV100523236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 100/413 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 39/144 reads (27%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA2 | c.935G>T p.G312V (on ENST00000614293; = p.G282V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.139); catalogued as rs866444534; called by muse, mutect2, varscan2
- AC069544.2 | c.834G>T p.R278S | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.227); catalogued as rs1170040940; called by muse, mutect2, varscan2
- ACO2 | c.2035C>T p.R679C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs747898560, COSV53443056; called by muse, mutect2, varscan2
- ACSBG1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV99357299; called by muse, mutect2
- ACTA2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99827159; called by muse, mutect2, varscan2
- ADAMTS7 | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs751627107; called by muse, mutect2, varscan2
- AHDC1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.056); catalogued as COSV99899071; called by muse, mutect2, varscan2
- AKIRIN1 | c.559C>G p.P187A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); catalogued as COSV100881972; called by muse, mutect2, varscan2
- AMN | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs1387555458; called by muse, mutect2, varscan2
- ANOS1 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 106/560 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV52915809; called by muse, mutect2, varscan2
- APTX | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1024283851; called by muse, mutect2, varscan2
- ARHGAP40 | c.492del p.L165Cfs*55 | Frame Shift Del (DEL) | VAF 15/110 reads (14%) | catalogued as rs780331526; called by mutect2, pindel, varscan2
- ASCL2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58713489; called by muse, varscan2
- BAG1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV65651663; called by muse, mutect2, varscan2
- BCL6 | c.1140C>G p.F380L | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV51653132; called by muse, varscan2
- BEND4 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as rs765527199, COSV72469116; called by muse, mutect2, varscan2
- BTBD16 | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 50/207 reads (24%) | catalogued as COSV53263068; called by muse, mutect2, varscan2
- C6orf132 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.04); catalogued as rs535484843; called by muse, mutect2, varscan2
- CCDC170 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV53343348; called by muse, mutect2, varscan2
- CCDC60 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV59550353; called by muse, mutect2, varscan2
- CCL13 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 20/232 reads (9%) | catalogued as rs1015764695; called by muse, mutect2
- CCT6B | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV58488039; called by muse, mutect2, varscan2
- CDT1 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV56347303, COSV56348860; called by muse, mutect2, varscan2
- CLCN4 | c.2244G>C p.Q748H | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101073936; called by muse, mutect2
- CLTCL1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782351246; called by muse, mutect2, varscan2
- COL26A1 | c.665G>C p.R222P (on ENST00000313669 / NM_001278563.3; = p.R220P on NM_133457.4) | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58129983; called by muse, mutect2, varscan2
- CPSF1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.121); catalogued as rs1210458451, COSV58235274; called by muse, mutect2, varscan2
- CST6 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 51/265 reads (19%) | catalogued as rs1201257007; called by muse, mutect2, varscan2
- CYP27C1 | c.387C>T p.F129= | Splice Region (SNP) | VAF 29/95 reads (31%) | catalogued as rs1400637991; called by muse, mutect2, varscan2
- CYP4F11 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV56125991; called by muse, mutect2, varscan2
- DDX21 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 64/896 reads (7%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.007); catalogued as rs771438821; called by muse, mutect2
- DEPDC5 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs1397187284, COSV99834831; called by muse, mutect2, varscan2
- DLC1 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs773334319; called by muse, mutect2, varscan2
- DLEC1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.605); catalogued as COSV100341107; called by muse, mutect2
- EFCC1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs1472684251; called by muse, mutect2, varscan2
- EIF1AX | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV65451522; called by muse, mutect2, varscan2
- EPHA5 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 41/197 reads (21%) | catalogued as COSV56630678; called by muse, mutect2, varscan2
- FBXL3 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs764791962, COSV62918319; called by muse, mutect2, varscan2
- FBXO27 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs780227318; called by muse, mutect2, varscan2
- FBXO28 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV64801306; called by muse, mutect2, varscan2
- FXYD4 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 77/495 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.782); catalogued as COSV72052621; called by muse, mutect2, varscan2
- FYTTD1 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV54082320; called by muse, mutect2, varscan2
- GEMIN5 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780229232; called by muse, varscan2
- GLS | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57845723; called by muse, mutect2, varscan2
- GLT8D2 | c.405G>A p.L135= | Splice Region (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100674041; called by muse, mutect2, varscan2
- GPR158 | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs138045559, COSV66269210; called by muse, mutect2, varscan2
- H1-10 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs765023771, COSV100412921, COSV100412961; called by mutect2, varscan2
- H2AC20 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 150/607 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV58612626; called by muse, mutect2, varscan2
- HBEGF | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV50183272; called by muse, mutect2, varscan2
- HMCN1 | c.4251G>T p.K1417N | Missense Mutation (SNP) | VAF 193/475 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1430343760, COSV54945492; called by muse, mutect2, varscan2
- HTR3D | c.228-8G>C | Splice Region (SNP) | VAF 25/200 reads (13%) | catalogued as COSV61913422; called by muse, mutect2, varscan2
- HYOU1 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs782493862; called by muse, mutect2, varscan2
- JAK2 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as rs770883479, COSV67663615; called by muse, mutect2, varscan2
- KANSL3 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 59/438 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV62619192; called by muse, mutect2, varscan2
- KCNF1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV99705527; called by muse, mutect2, varscan2
- KIF26B | c.4642G>C p.E1548Q | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV63640901; called by muse, mutect2, varscan2
- KMT2A | c.6392C>G p.S2131C | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV63291420; called by muse, mutect2, varscan2
- KRTAP26-1 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV62128449; called by muse, mutect2, varscan2
- LAMTOR2 | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as COSV63108892; called by muse, mutect2, varscan2
- LARP1 | c.3074G>A p.R1025Q (on ENST00000518297 / NM_033551.3; = p.R948Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs200806332, COSV100304063; called by muse, mutect2, varscan2
- LIPT2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as rs949529835; called by muse, mutect2, varscan2
- LTBP4 | c.1810G>C p.E604Q (on ENST00000308370 / NM_001042544.1; = p.E567Q on NM_003573.2) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99198231; called by muse, mutect2, varscan2
- MAGIX | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1205431191; called by muse, mutect2
- MAN2B1 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 50/204 reads (25%) | catalogued as rs1179633090, COSV99666975; called by muse, mutect2, varscan2
- MAPK15 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100567759, COSV100568161; called by muse, mutect2, varscan2
- MAST1 | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99263223; called by muse, mutect2, varscan2
- MATN1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1475850568; called by muse, varscan2
- MMP16 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 94/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164638; called by muse, mutect2, varscan2
- MROH2B | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68181233, COSV68191170; called by muse, mutect2, varscan2
- MRPS30 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs755437892; called by mutect2, varscan2
- MS4A2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV54013125; called by muse, mutect2, varscan2
- MUC4 | c.2766C>G p.I922M | Missense Mutation (SNP) | VAF 66/751 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.318); catalogued as COSV62186476; called by muse, mutect2
- MXRA8 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV58511445; called by muse, mutect2
- MYO1H | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as rs1207379075; called by muse, varscan2
- NADK2 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56939307; called by muse, mutect2, varscan2
- NANOG | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs1456382970; called by muse, mutect2, varscan2
- NAPA | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV54548609; called by mutect2, varscan2
- NCAPD2 | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 122/538 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1016312186, COSV59698747; called by muse, mutect2, varscan2
- NFE2L2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 110/242 reads (45%) | catalogued as COSV67960579; called by muse, mutect2, varscan2
- NOP56 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1290994038; called by muse, mutect2, varscan2
- NPR1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 78/370 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1429961482, COSV100902079; called by muse, mutect2, varscan2
- NSD1 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV61780504; called by muse, mutect2, varscan2
- NXF3 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV67704961; called by muse, mutect2, varscan2
- OR8H3 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs186537092; called by muse, mutect2, varscan2
- PCDH9 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60528623; called by muse, mutect2, varscan2
- PDGFRA | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 93/436 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV57268651; called by muse, mutect2, varscan2
- PDXK | c.796G>C p.V266L | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV52362318; called by muse, varscan2
- PDZRN4 | c.1669C>T p.R557C (on ENST00000402685 / NM_001164595.2; = p.R299C on NM_013377.4) | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs752112201, COSV54210006; called by muse, mutect2, varscan2
- PNMA8A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1337183385, COSV100562337; called by muse, mutect2, varscan2
- PRKCB | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57775144; called by muse, mutect2, varscan2
- PRKG1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 232/657 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1178803378; called by muse, mutect2, varscan2
- PSG7 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 60/554 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as COSV68446555; called by muse, mutect2, varscan2
- RGL3 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs1476886650; called by muse, mutect2, varscan2
- SERPINB12 | c.654C>G p.N218K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777950250; called by muse, mutect2
- SERPINB3 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52190082, COSV99033279, COSV99379872; called by muse, mutect2, varscan2
- SETX | c.5306G>C p.R1769T | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99810502, COSV99811260; called by muse, mutect2, varscan2
- SFN | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as rs779455161; called by muse, mutect2, varscan2
- SLC7A13 | c.8G>C p.R3T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52537535, COSV99879201; called by muse, mutect2, varscan2
- SP110 | c.1779G>C p.K593N | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV51246535, COSV99283281; called by muse, mutect2, varscan2
- SPTAN1 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 140/534 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63986024; called by muse, mutect2, varscan2
- SPTY2D1 | c.1496C>G p.S499* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100311917; called by muse, mutect2, varscan2
- SYCE1 | c.664C>T p.P222S (on ENST00000343131 / NM_001143764.3; = p.P186S on NM_130784.3) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs751465933; called by muse, mutect2, varscan2
- SZT2 | c.4979C>G p.S1660* (on ENST00000634258 / NM_001365999.1; = p.S1603* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV65171387; called by muse, mutect2, varscan2
- TEX15 | c.5617G>A p.E1873K (on ENST00000256246; = p.E2256K on NM_001350162.2) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755125212, COSV56344222; called by muse, mutect2, varscan2
- TNFSF10 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 46/543 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs755195766; called by muse, mutect2
- TNXB | c.9343G>A p.E3115K (on ENST00000647633; = p.E2868K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/431 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs764870462, COSV100926401; called by muse, mutect2, varscan2
- TRIM8 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs1186627221; called by muse, mutect2, varscan2
- UQCRC2 | c.720G>C p.M240I | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746331947; called by muse, mutect2, varscan2
- UTP25 | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 83/487 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71965790; called by muse, mutect2, varscan2
- VGLL1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65702879, COSV65702983; called by muse, mutect2, varscan2
- VPS45 | c.374T>C p.F125S | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1227921940; called by muse, mutect2
- WASHC5 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59199161; called by muse, varscan2
- WDR35 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 49/189 reads (26%) | catalogued as COSV99852930; called by muse, mutect2, varscan2
- ZFP30 | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV63623155; called by muse, mutect2, varscan2
- ZGRF1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52201486; called by muse, mutect2, varscan2
- ZNF197 | c.770-1G>C p.X257_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV60360565; called by muse, mutect2
- ZNF34 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58639385; called by muse, mutect2, varscan2
- ZNF442 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.971); catalogued as rs769313262; called by muse, mutect2, varscan2
- ZNF467 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs778252632; called by muse, mutect2, varscan2
- ACADM | c.217-4C>G | Splice Region (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2, varscan2
- ADNP | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 88/657 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADRB2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 196/642 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AFF3 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AGO1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AGXT | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AIFM1 | c.424G>C p.A142P | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK7 | c.675A>T p.L225F | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AL445989.1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 55/533 reads (10%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- ANKRD12 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANKRD62 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- AP3B2 | c.1563T>A p.D521E | Missense Mutation (SNP) | VAF 53/452 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP31 | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 191/1086 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARID1A | c.2584_2632del p.S862Rfs*13 | Frame Shift Del (DEL) | VAF 22/213 reads (10%) | called by mutect2, pindel
- ARSK | c.1097-1G>C p.X366_splice | Splice Site (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- ATG4A | c.1062A>C p.K354N | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP1B4 | c.637G>C p.E213Q (on ENST00000218008 / NM_001142447.3; = p.E209Q on NM_012069.5) | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATRAID | c.156G>C p.R52S | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- AZIN1 | c.478A>T p.N160Y | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- B4GALNT1 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BCL11A | c.556G>C p.E186Q (on ENST00000335712 / NM_001365609.1; = p.E220Q on NM_018014.4) | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- BCORL1 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- BEND5 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.31); called by muse, mutect2
- C12orf66 | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2
- C1orf226 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CABIN1 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAD | c.3294G>C p.M1098I | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CALB1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, varscan2
- CAPN9 | c.2027T>G p.I676S | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CARF | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 56/483 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL3 | c.2706+1G>T p.X902_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- CBX4 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); called by mutect2, varscan2
- CCDC191 | c.2213C>A p.A738E | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC93 | c.1622C>G p.S541* | Nonsense Mutation (SNP) | VAF 73/336 reads (22%) | called by muse, mutect2, varscan2
- CCL24 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by mutect2, varscan2
- CCNB3 | c.659A>C p.E220A | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- CDC42BPB | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP295NL | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- CHML | c.1971G>C p.*657Yext*21 | Nonstop Mutation (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- CIBAR1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT1 | c.3960G>C p.K1320N | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNRIP1 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 93/584 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- COL12A1 | c.8864C>A p.A2955D | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- CSDE1 | c.682G>A p.D228N (on ENST00000358528 / NM_001007553.3; = p.D197N on NM_007158.6) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD3 | c.3885+2T>C p.X1295_splice (on ENST00000297405 / NM_001363185.1; = p.X1191_splice on NM_052900.3) | Splice Site (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- CSN1S1 | c.195+2T>A p.X65_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- CUBN | c.1639A>G p.R547G | Missense Mutation (SNP) | VAF 46/709 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- DCAF17 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 117/808 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DCHS1 | c.9083C>G p.S3028* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- DDX11 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DDX4 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH7 | c.1599A>G p.I533M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- DNAJC9 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DOCK11 | c.4487C>G p.S1496* | Nonsense Mutation (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- DUS3L | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYRK4 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ECE1 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 122/573 reads (21%) | called by muse, mutect2, varscan2
- ECT2 | c.211-1G>C p.X71_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- EIF3D | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- EIF4A1 | c.1021G>T p.V341F | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EPB41L1 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 143/461 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- F8 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 98/554 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM186A | c.2270C>G p.S757* | Nonsense Mutation (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- FANCM | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 151/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT4 | c.5370C>G p.D1790E | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBXO4 | c.843del p.V282Cfs*5 | Frame Shift Del (DEL) | VAF 95/550 reads (17%) | called by mutect2, pindel, varscan2
- FMN2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- FMN2 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, varscan2
- FOXP2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 34/574 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- FTSJ3 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT5 | c.6T>A p.D2E | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FYB2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 60/160 reads (38%) | called by muse, varscan2
- GATA5 | c.914-5_916del p.X305_splice | Splice Site (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel
- GCKR | c.795del p.T266Pfs*10 | Frame Shift Del (DEL) | VAF 238/769 reads (31%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.1612T>G p.S538A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.124); called by muse, varscan2
- GRM1 | c.3575C>A p.S1192Y | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- HACE1 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HAUS3 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- HEATR3 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- HECTD4 | c.8860G>C p.E2954Q | Missense Mutation (SNP) | VAF 96/719 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC5 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLA-C | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLTF | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HPS3 | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, varscan2
- HSH2D | c.909_911del p.P304del | In Frame Del (DEL) | VAF 34/221 reads (15%) | called by pindel, varscan2
- HSPB6 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HTT | c.2566C>G p.L856V | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGKV2D-28 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by mutect2, varscan2
- IGSF11 | c.238C>T p.Q80* (on ENST00000393775 / NM_001015887.3; = p.Q79* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- IHO1 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ITGB3 | c.1974C>G p.N658K | Missense Mutation (SNP) | VAF 165/808 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGB6 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNS1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KDM3A | c.2550C>G p.I850M | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KDR | c.1851C>G p.F617L | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHK | c.608C>A p.S203* | Nonsense Mutation (SNP) | VAF 185/537 reads (34%) | called by muse, mutect2, varscan2
- KL | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- KLHL13 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.326); called by muse, mutect2
- KLHL36 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KRT82 | c.483C>G p.C161W | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LEKR1 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LEUTX | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LTN1 | c.3459G>T p.W1153C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, varscan2
- MACF1 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- MACF1 | c.20317G>C p.D6773H (on ENST00000372915; = p.D4818H on NM_012090.5) | Missense Mutation (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- MAP3K19 | c.2917C>G p.L973V | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP6 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- MAPRE3 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEI1 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIA2 | c.1903_1906del p.S635Dfs*38 | Frame Shift Del (DEL) | VAF 55/184 reads (30%) | called by mutect2, pindel, varscan2
- MINDY4B | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MLLT10 | c.2668C>T p.P890S (on ENST00000307729 / NM_001195626.3; = p.P906S on NM_004641.3) | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MORC1 | c.6C>A p.D2E | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- MPL | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 86/399 reads (22%) | called by muse, mutect2, varscan2
- MUC5B | c.7211T>A p.I2404N | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MYH7B | c.5775C>A p.S1925R | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- MYH7B | c.5776T>A p.Y1926N | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NBPF22P | n.1167A>T | Splice Region (SNP) | VAF 64/227 reads (28%) | called by muse, mutect2, varscan2
- NDST3 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NEFH | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NFATC1 | c.1699C>T p.H567Y | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NKIRAS1 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, varscan2
- NLRP6 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NUMA1 | c.4943T>A p.L1648Q | Missense Mutation (SNP) | VAF 87/548 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OBI1 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); called by muse, mutect2
- OBSCN | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 77/397 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- OLA1 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 294/527 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPA1 | c.635G>C p.R212T (on ENST00000361510 / NM_130837.3; = p.R194T on NM_015560.3) | Missense Mutation (SNP) | VAF 121/771 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- OR10A7 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- OR10X1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- OR8S1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OS9 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OSMR | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OTOF | c.766-1G>A p.X256_splice | Splice Site (SNP) | VAF 84/238 reads (35%) | called by muse, mutect2
- OVCH2 | c.1580C>G p.S527* | Nonsense Mutation (SNP) | VAF 60/178 reads (34%) | called by muse, mutect2, varscan2
- PARD6B | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 60/535 reads (11%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PCIF1 | c.1935G>C p.Q645H | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE3B | c.2167T>G p.Y723D | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PGK1 | c.1179C>G p.S393R | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGA | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2B | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PKD2 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 104/564 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLA2G15 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLAU | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PLEKHA6 | c.1895G>C p.W632S | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PNPT1 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POR | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- POU5F1 | c.494_524del p.A165Vfs*67 | Frame Shift Del (DEL) | VAF 32/398 reads (8%) | called by mutect2, pindel
- PPARGC1B | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPP1R12B | c.1228A>T p.T410S | Missense Mutation (SNP) | VAF 170/523 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP3CB | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- PRPF38B | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PTK7 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- PTPN2 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 94/476 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRC | c.1133T>A p.F378Y | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PWWP3B | c.764A>G p.K255R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3322C>T p.Q1108* | Nonsense Mutation (SNP) | VAF 89/489 reads (18%) | called by muse, mutect2, varscan2
- RAB5A | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | called by muse, varscan2
- RAPH1 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RASA2 | c.2330-1G>C p.X777_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- RDH10 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RESF1 | c.2549T>G p.V850G | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS2 | c.635G>T p.*212Lext*27 | Nonstop Mutation (SNP) | VAF 70/463 reads (15%) | called by muse, mutect2, varscan2
- RNF148 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- RYR3 | c.12056G>C p.S4019T (on ENST00000389232; = p.S4020T on NM_001036.6) | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SAMD9 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 82/413 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SERGEF | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3TC1 | c.3609C>G p.H1203Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SH3TC2 | c.1177+3G>A | Splice Region (SNP) | VAF 145/472 reads (31%) | called by muse, mutect2, varscan2
- SHANK2 | c.4197_4198delinsTGA p.D1400Efs*4 | Frame Shift Ins (INS) | VAF 30/300 reads (10%) | called by pindel, varscan2*
- SLC16A8 | c.1278C>A p.F426L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SLC29A2 | c.1255C>G p.P419A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A4 | c.320C>T p.S107F (on ENST00000517878 / NM_001286646.2; = p.S56F on NM_001080431.2) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SPP1 | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, varscan2
- SPPL3 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SRCIN1 | c.1857G>C p.Q619H (on ENST00000621492; = p.Q585H on NM_025248.3) | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, varscan2
- SUGP1 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 70/409 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SULT1B1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.048); called by muse, mutect2
- SYCP1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TASOR | c.1828G>A p.E610K (on ENST00000355628 / NM_001365636.2; = p.E214K on NM_015224.3) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TASOR2 | c.233A>T p.Y78F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TERB1 | c.1548A>T p.K516N | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TESK1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TMEM106B | c.528del p.I176Mfs*6 | Frame Shift Del (DEL) | VAF 59/175 reads (34%) | called by mutect2, pindel, varscan2
- TMEM245 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TMTC3 | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNRC6A | c.3323C>G p.S1108C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TRAPPC11 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- TRBC2 | c.173C>G p.T58R | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM22 | c.505A>T p.R169* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- TRIM24 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2
- TRIM58 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- TRIM67 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- TRIM67 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TSHR | c.1247T>C p.F416S | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN6 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TTN | c.46573A>G p.I15525V (on ENST00000591111; = p.I8101V on NM_003319.4) | Missense Mutation (SNP) | VAF 72/116 reads (62%) | PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UBE2N | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UTP4 | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- WWOX | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by mutect2, varscan2
- XRN2 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, varscan2
- ZNF155 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF418 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- ZNF75D | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF784 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.29); called by muse, varscan2
- ABCB10 | c.354C>T p.F118= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1373675680; called by muse, mutect2, varscan2
- ABCG2 | c.621G>A p.L207= | Silent (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- AC004922.1 | c.144C>G p.L48= | Silent (SNP) | VAF 43/273 reads (16%) | called by muse, mutect2, varscan2
- ACTR1A | c.42C>T p.I14= | Silent (SNP) | VAF 44/235 reads (19%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1947C>G p.P649= | Silent (SNP) | VAF 52/276 reads (19%) | called by muse, mutect2, varscan2
- AMIGO1 | c.732G>C p.V244= | Silent (SNP) | VAF 66/291 reads (23%) | called by muse, mutect2, varscan2
- ANO5 | c.2331G>C p.V777= | Silent (SNP) | VAF 71/247 reads (29%) | catalogued as rs780695828; called by muse, mutect2, varscan2
- ARHGEF4 | c.459C>G p.V153= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- ASTN1 | c.3150C>T p.I1050= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as rs150457018; called by muse, mutect2, varscan2
- ATP10A | c.4155G>T p.L1385= | Silent (SNP) | VAF 54/230 reads (23%) | called by muse, mutect2, varscan2
- ATP6V1E2 | c.294G>A p.A98= | Silent (SNP) | VAF 73/363 reads (20%) | catalogued as rs147271327; called by muse, mutect2, varscan2
- B3GALT2 | c.273G>A p.L91= | Silent (SNP) | VAF 135/465 reads (29%) | called by muse, mutect2, varscan2
- BBS4 | c.570C>G p.V190= | Silent (SNP) | VAF 89/466 reads (19%) | catalogued as rs1468725330; called by muse, varscan2
- BEND4 | c.792T>C p.T264= | Silent (SNP) | VAF 56/343 reads (16%) | called by muse, mutect2, varscan2
- BUB1B | c.1779C>T p.I593= | Silent (SNP) | VAF 103/260 reads (40%) | called by muse, mutect2, varscan2
- C1orf226 | c.732C>T p.S244= | Silent (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- CA2 | c.630G>A p.V210= | Silent (SNP) | VAF 58/489 reads (12%) | catalogued as CX013499; called by muse, mutect2, varscan2
- CBR1 | c.165G>C p.L55= | Silent (SNP) | VAF 46/216 reads (21%) | called by muse, mutect2, varscan2
- CHST7 | c.627C>A p.G209= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV99333042; called by muse, mutect2, varscan2
- COBL | c.879G>A p.V293= | Silent (SNP) | VAF 78/326 reads (24%) | catalogued as COSV54354485; called by muse, mutect2, varscan2
- COL6A2 | c.75C>T p.V25= | Silent (SNP) | VAF 44/217 reads (20%) | called by muse, varscan2
- CYP2F1 | c.723G>C p.L241= | Silent (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- CYP4A11 | c.85C>T p.L29= | Silent (SNP) | VAF 40/234 reads (17%) | called by muse, mutect2, varscan2
- CYP8B1 | c.786G>A p.L262= | Silent (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- DNER | c.933G>A p.E311= | Silent (SNP) | VAF 86/302 reads (28%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2691C>T p.P897= | Silent (SNP) | VAF 31/190 reads (16%) | called by muse, mutect2, varscan2
- EMILIN3 | c.312C>G p.P104= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2
- ERBB3 | c.3093C>T p.L1031= | Silent (SNP) | VAF 116/418 reads (28%) | catalogued as COSV99915700; called by muse, mutect2, varscan2
- FAT4 | c.5241C>G p.L1747= | Silent (SNP) | VAF 58/196 reads (30%) | called by muse, varscan2
- FER1L5 | c.5661G>A p.Q1887= (on ENST00000623019; = p.Q1851= on NM_001293083.2) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs775731259; called by muse, mutect2, varscan2
- FLNA | c.2481C>T p.I827= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as rs1276120463; called by muse, mutect2, varscan2
- GH2 | c.189G>A p.L63= | Silent (SNP) | VAF 175/677 reads (26%) | catalogued as rs1373162915; called by muse, mutect2, varscan2
- GMIP | c.1533C>T p.F511= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs555991456; called by muse, mutect2, varscan2
- GRIK3 | c.510C>T p.L170= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV66140173; called by muse, mutect2, varscan2
- GRIPAP1 | c.2046G>C p.S682= | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- HIPK4 | c.135C>T p.D45= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as rs536497388; called by muse, mutect2, varscan2
- HMGN5 | c.57A>G p.R19= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs910942509; called by muse, mutect2, varscan2
- HS1BP3 | c.224G>A p.*75= | Silent (SNP) | VAF 32/153 reads (21%) | called by muse, varscan2
- HSPA1L | c.1143C>T p.I381= | Silent (SNP) | VAF 13/213 reads (6%) | catalogued as rs777727278; called by muse, mutect2
- IGSF9 | c.3012G>T p.L1004= (on ENST00000368094 / NM_001135050.2; = p.L988= on NM_020789.4) | Silent (SNP) | VAF 43/270 reads (16%) | called by muse, mutect2, varscan2
- IL31RA | c.1725C>T p.L575= | Silent (SNP) | VAF 128/451 reads (28%) | called by muse, mutect2, varscan2
- ITIH6 | c.495G>A p.L165= | Silent (SNP) | VAF 111/546 reads (20%) | called by muse, mutect2, varscan2
- KCNH4 | c.1161G>A p.E387= | Silent (SNP) | VAF 60/262 reads (23%) | catalogued as rs1232875107; called by muse, mutect2, varscan2
- KIAA0753 | c.2529G>A p.V843= | Silent (SNP) | VAF 60/275 reads (22%) | catalogued as COSV63818205; called by muse, mutect2, varscan2
- KIAA1549 | c.3753C>G p.L1251= | Silent (SNP) | VAF 59/325 reads (18%) | called by muse, mutect2, varscan2
- KPRP | c.486C>T p.V162= | Silent (SNP) | VAF 43/197 reads (22%) | called by muse, mutect2, varscan2
- LAMA5 | c.8364C>T p.R2788= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- LRRC10B | c.666C>T p.V222= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs770067164; called by muse, mutect2, varscan2
- MALSU1 | c.303G>C p.L101= | Silent (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- MIB1 | c.1614C>G p.V538= | Silent (SNP) | VAF 62/320 reads (19%) | called by muse, varscan2
- MLXIPL | c.492C>T p.V164= | Silent (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1584C>T p.I528= (on ENST00000374979 / NM_001308027.2; = p.I476= on NM_024631.4) | Silent (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- MYF5 | c.414G>A p.L138= | Silent (SNP) | VAF 39/221 reads (18%) | catalogued as COSV57354804, COSV57355636; called by muse, mutect2, varscan2
- NECAP2 | c.36C>G p.V12= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs1418181625, COSV59188757, COSV59188773; called by muse, mutect2, varscan2
- NNT | c.1407C>T p.F469= | Silent (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- NPAS1 | c.1599G>T p.V533= | Silent (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- NUTM2B | c.2520C>G p.L840= | Silent (SNP) | VAF 115/600 reads (19%) | called by muse, mutect2, varscan2
- OR4E2 | c.924C>T p.F308= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV57732319; called by muse, mutect2, varscan2
- OR52W1 | c.879C>A p.L293= | Silent (SNP) | VAF 121/300 reads (40%) | called by muse, mutect2, varscan2
- OTOP1 | c.855C>G p.L285= | Silent (SNP) | VAF 68/299 reads (23%) | catalogued as rs1268061874; called by muse, mutect2, varscan2
- OXR1 | c.2349G>A p.L783= (on ENST00000442977 / NM_001198532.1; = p.L755= on NM_018002.3) | Silent (SNP) | VAF 113/350 reads (32%) | catalogued as COSV52424968; called by muse, mutect2, varscan2
- PAPOLB | c.675G>C p.L225= | Silent (SNP) | VAF 94/186 reads (51%) | catalogued as rs904664360; called by muse, mutect2, varscan2
- PLA2G2C | c.327G>C p.L109= | Silent (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- POMGNT2 | c.1626G>A p.Q542= | Silent (SNP) | VAF 75/399 reads (19%) | called by muse, mutect2, varscan2
- PRKACG | c.855C>T p.L285= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs774072896, COSV99598630; called by muse, mutect2, varscan2
- RBL1 | c.2973G>A p.K991= | Silent (SNP) | VAF 49/259 reads (19%) | catalogued as rs1318227101; called by muse, mutect2, varscan2
- RELA | c.390C>T p.I130= | Silent (SNP) | VAF 71/347 reads (20%) | called by muse, mutect2, varscan2
- RIPOR3 | c.648C>G p.R216= | Silent (SNP) | VAF 177/311 reads (57%) | called by muse, mutect2, varscan2
- RYR2 | c.6900C>T p.D2300= | Silent (SNP) | VAF 88/299 reads (29%) | called by muse, mutect2, varscan2
- SASS6 | c.1596C>T p.S532= | Silent (SNP) | VAF 50/210 reads (24%) | catalogued as COSV99791178; called by muse, mutect2, varscan2
- SGF29 | c.186C>G p.L62= | Silent (SNP) | VAF 83/309 reads (27%) | called by muse, mutect2, varscan2
- SLC38A8 | c.99C>T p.L33= | Silent (SNP) | VAF 34/183 reads (19%) | catalogued as rs766376941, COSV100230732; called by muse, mutect2, varscan2
- SMOC1 | c.768C>T p.L256= | Silent (SNP) | VAF 78/268 reads (29%) | catalogued as rs1052039128; called by muse, varscan2
- SPATC1 | c.240G>C p.V80= | Silent (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- SYTL2 | c.213C>T p.I71= | Silent (SNP) | VAF 87/209 reads (42%) | catalogued as rs527259541, COSV60360063; called by muse, mutect2, varscan2
- TAF6 | c.1008G>A p.L336= | Silent (SNP) | VAF 36/250 reads (14%) | called by muse, mutect2, varscan2
- TMEM130 | c.939C>T p.F313= | Silent (SNP) | VAF 41/208 reads (20%) | called by muse, mutect2, varscan2
- TNC | c.4941C>T p.F1647= | Silent (SNP) | VAF 69/460 reads (15%) | catalogued as rs201689087, COSV60788203; called by muse, mutect2, varscan2
- TNXB | c.2097G>A p.R699= | Silent (SNP) | VAF 87/155 reads (56%) | called by muse, mutect2, varscan2
- TRPM2 | c.393C>G p.V131= | Silent (SNP) | VAF 44/202 reads (22%) | called by muse, mutect2, varscan2
- UBR4 | c.9177G>C p.L3059= | Silent (SNP) | VAF 46/337 reads (14%) | called by muse, mutect2, varscan2
- USH1G | c.465G>C p.R155= | Silent (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- VWC2 | c.660C>T p.F220= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1410696163, COSV100514376; called by muse, varscan2
- VWF | c.4428C>T p.V1476= | Silent (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- WRN | c.1986C>A p.I662= | Silent (SNP) | VAF 97/322 reads (30%) | called by muse, mutect2, varscan2
- ZNF408 | c.1455C>T p.N485= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- ZNF513 | c.534C>T p.F178= | Silent (SNP) | VAF 74/271 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP27P2 | n.158_167del | RNA (DEL) | VAF 11/103 reads (11%) | called by mutect2, pindel
- ATP6V1G1 | c.-16C>G | 5'UTR (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- BIRC2 | c.-1159G>C | 5'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- BZW1 | c.-10-325G>C | Intron (SNP) | VAF 30/514 reads (6%) | called by muse, mutect2
- C19orf12 | chr19:29700982 C>G | 3'Flank (SNP) | VAF 65/247 reads (26%) | called by muse, mutect2, varscan2
- CD81 | c.562-47G>A | Intron (SNP) | VAF 35/98 reads (36%) | catalogued as rs764648595; called by muse, varscan2
- CDHR1 | chr10:84219253 C>G | 3'Flank (SNP) | VAF 48/178 reads (27%) | catalogued as rs771233990; called by muse, mutect2, varscan2
- CDK16 | c.-256C>G | 5'UTR (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4727-18C>G | Intron (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- COLEC11 | chr2:3594951 G>T | 5'Flank (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5568-1081C>T | Intron (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- CTNNB1 | c.-18G>C | 5'UTR (SNP) | VAF 179/362 reads (49%) | called by muse, mutect2, varscan2
- DIP2A | c.4032-91G>A | Intron (SNP) | VAF 83/388 reads (21%) | called by muse, mutect2, varscan2
- DMAC2 | chr19:41440180 C>A | 5'Flank (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- DNM1P46 | n.861T>G | RNA (SNP) | VAF 70/282 reads (25%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7828C>G | Intron (SNP) | VAF 51/257 reads (20%) | called by muse, mutect2, varscan2
- FAM126B | c.-22G>C | 5'UTR (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- FBH1 | c.1+4838G>T | Intron (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- FBXO3 | c.1239+26G>C | Intron (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- FXR2 | c.134+24C>G | Intron (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- GET4 | c.317-224C>T | Intron (SNP) | VAF 25/133 reads (19%) | catalogued as rs768560774; called by muse, mutect2, varscan2
- GFUS | c.391-21C>T | Intron (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- GH2 | c.456+108G>A | Intron (SNP) | VAF 48/195 reads (25%) | catalogued as rs1176924404; called by muse, mutect2, varscan2
- H2BC15 | c.377+13109_377+13111del | Intron (DEL) | VAF 14/48 reads (29%) | catalogued as rs1292918489; called by pindel, varscan2
- HDAC7 | c.2239-38C>G | Intron (SNP) | VAF 41/208 reads (20%) | called by muse, mutect2, varscan2
- HROB | c.-20G>A | 5'UTR (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- HSPA7 | n.300C>T | RNA (SNP) | VAF 25/314 reads (8%) | called by muse, mutect2
- ILDR1 | c.*136G>C | 3'UTR (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- KLF7 | chr2:207167180 G>A | 5'Flank (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- LHX9 | c.-350C>G | 5'UTR (SNP) | VAF 215/575 reads (37%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.249+7059T>C | Intron (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- MACF1 | c.16491+527G>A | Intron (SNP) | VAF 56/625 reads (9%) | called by muse, mutect2
- MTPN | c.*2596C>G | 3'UTR (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1235-3241A>G | Intron (SNP) | VAF 106/402 reads (26%) | catalogued as rs1440653935; called by muse, mutect2, varscan2
- NANP | c.-4C>T | 5'UTR (SNP) | VAF 16/91 reads (18%) | catalogued as rs752356313; called by mutect2, varscan2
- NETO1 | c.-18C>T | 5'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- NGF | c.*23del | 3'UTR (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- PARP10 | chr8:143973427 C>G | 3'Flank (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- PARP14 | c.4941+99_4941+100dup | Intron (INS) | VAF 13/72 reads (18%) | called by mutect2, varscan2
- PDLIM5 | c.920+613C>G | Intron (SNP) | VAF 196/780 reads (25%) | catalogued as COSV58752215; called by muse, mutect2, varscan2
- PIGS | chr17:28571529 G>A | 5'Flank (SNP) | VAF 21/66 reads (32%) | catalogued as rs751657630; called by muse, mutect2, varscan2
- PLP2 | c.345+64C>T | Intron (SNP) | VAF 56/302 reads (19%) | called by muse, mutect2, varscan2
- POMGNT1 | c.534+67C>G | Intron (SNP) | VAF 83/307 reads (27%) | called by muse, mutect2, varscan2
- PSG1 | c.1243+38G>T | Intron (SNP) | VAF 40/137 reads (29%) | catalogued as rs376621024; called by muse, mutect2, varscan2
- RARRES1 | chr3:158734012 C>T | 5'Flank (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- RORC | c.-21C>G | 5'UTR (SNP) | VAF 51/137 reads (37%) | catalogued as COSV100561847; called by muse, mutect2, varscan2
- SAC3D1 | c.-7-61C>T | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs1342360440; called by muse, mutect2, varscan2
- SDHAP1 | n.1513C>T | RNA (SNP) | VAF 74/622 reads (12%) | catalogued as rs753529637; called by mutect2, varscan2
- SPEF2 | c.2398+1492G>C | Intron (SNP) | VAF 51/311 reads (16%) | called by muse, mutect2, varscan2
- SSX6P | chrX:48117084 G>A | 3'Flank (SNP) | VAF 11/274 reads (4%) | catalogued as rs782737576; called by muse, mutect2
- TBX3 | c.657+50C>G | Intron (SNP) | VAF 68/394 reads (17%) | called by muse, mutect2, varscan2
- TEX37 | c.-1C>T | 5'UTR (SNP) | VAF 70/237 reads (30%) | catalogued as rs763851340; called by muse, mutect2, varscan2
- TJP1 | c.5152+55C>G | Intron (SNP) | VAF 31/80 reads (39%) | catalogued as rs761419687, COSV62042424; called by muse, mutect2, varscan2
- TJP2 | c.61-7360G>C | Intron (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2, varscan2
- TM4SF19 | chr3:196320062 G>C | 3'Flank (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- TRMT9B | chr8:13031367 C>A | 3'Flank (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- TSPYL4 | chr6:116258510 C>T | 5'Flank (SNP) | VAF 71/251 reads (28%) | catalogued as rs1383204705; called by muse, mutect2, varscan2
- TTN | c.10361-5370G>A | Intron (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.10360+4058T>C | Intron (SNP) | VAF 99/212 reads (47%) | catalogued as rs540830377; called by muse, mutect2, varscan2
- ZWILCH | c.521-16C>G | Intron (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
